Somatic mutation profile of tumor specimen TCGA-B2-4099-01A (aliquot TCGA-B2-4099-01A-02D-1251-10) from TCGA case TCGA-B2-4099, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 83.1 years (30,355 days).
Specimen TCGA-B2-4099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c6ecfa5-768e-4943-9e5f-4148cfa5c257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-4099-10A (Blood Derived Normal), aliquot TCGA-B2-4099-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5000ae29-bcfb-44f4-81bc-0dc04892206b

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Frame Shift Del 7, Frame Shift Ins 3, Splice Site 2, Nonsense Mutation 2, Intron 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG2 | c.1096A>C p.N366H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs766486498, COSV53125179; called by muse, mutect2, varscan2
- ADAM29 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as rs945282633, COSV63663914; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 54/444 reads (12%) | catalogued as rs535192849; called by mutect2, varscan2
- CDH18 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 194/562 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV56924826; called by muse, mutect2, varscan2
- CERS2 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV54983364; called by muse, mutect2, varscan2
- CRISPLD1 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV51548417, COSV51552951; called by muse, mutect2
- CUL1 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57388865; called by muse, mutect2, varscan2
- DCAF12L1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64421832; called by muse, mutect2, varscan2
- DENND1C | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57568706; called by muse, mutect2
- DMD | c.10223+1G>T p.X3408_splice | Splice Site (SNP) | VAF 107/179 reads (60%) | catalogued as CS1510030, CS930792, CS971710, COSV58912681; called by muse, mutect2, varscan2
- ELMO3 | c.1052G>A p.R351Q (on ENST00000652269; = p.R298Q on NM_024712.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs777708052, COSV100681496, COSV62606638; called by muse, mutect2, varscan2
- FNIP1 | c.1557A>C p.L519F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57196644; called by muse, mutect2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 152/1020 reads (15%) | catalogued as rs548474277; called by mutect2, varscan2
- HEATR6 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV51744021, COSV51745822; called by muse, mutect2, varscan2
- KATNIP | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.281); catalogued as COSV55181334, COSV55192900; called by muse, mutect2, varscan2
- KIAA0895L | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV51783271; called by muse, mutect2, varscan2
- KIF19 | c.1097G>T p.S366I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1181893676, COSV63429552; called by muse, mutect2, varscan2
- KLK14 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50068690; called by muse, mutect2
- LRRC7 | c.2263G>C p.V755L (on ENST00000651989 / NM_001370785.2; = p.V722L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/606 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV50465286; called by muse, mutect2
- LSMEM2 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV57113882; called by muse, mutect2, varscan2
- MAD2L1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.067); catalogued as COSV56636962; called by muse, mutect2, varscan2
- MICAL2 | c.5616G>T p.M1872I | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV56286181; called by muse, mutect2, varscan2
- MTCL1 | c.4685C>T p.P1562L (on ENST00000306329 / NM_001378206.1; = p.P1243L on NM_015210.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1004090574, COSV60406437; called by muse, mutect2, varscan2
- MYH8 | c.4573C>T p.Q1525* | Nonsense Mutation (SNP) | VAF 192/600 reads (32%) | catalogued as rs775373801, COSV67965739; called by muse, mutect2, varscan2
- MYT1L | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV67721089; called by muse, mutect2, varscan2
- NLRP5 | c.570T>G p.I190M | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV66764777, COSV66766532; called by muse, mutect2
- NOSIP | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV59198865; called by muse, mutect2, varscan2
- NSD1 | c.4189C>G p.P1397A | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV61776753; called by muse, mutect2, varscan2
- OR5H1 | c.921dup p.H308Tfs*3 | Frame Shift Ins (INS) | VAF 36/175 reads (21%) | catalogued as rs750155763; called by mutect2, varscan2
- PTPN13 | c.5645C>T p.P1882L (on ENST00000411767 / NM_080683.3; = p.P1863L on NM_006264.3) | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1272140271, COSV100363915, COSV57408326; called by muse, mutect2, varscan2
- RAB11FIP2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV62925277; called by muse, mutect2, varscan2
- REM1 | c.102C>G p.S34R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52428347, COSV99147495; called by muse, mutect2, varscan2
- RUFY3 | c.895-1G>T p.X299_splice | Splice Site (SNP) | VAF 118/346 reads (34%) | catalogued as COSV56913877; called by muse, mutect2, varscan2
- SLC16A9 | c.758T>A p.L253H | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV68098987; called by muse, mutect2, varscan2
- SPHKAP | c.4584C>A p.D1528E | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV60880484; called by muse, mutect2
- STAB2 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141685549; called by muse, mutect2, varscan2
- SYNJ2BP | c.327T>A p.H109Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.198); catalogued as COSV56445755; called by muse, mutect2, varscan2
- TGFBI | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV59351444; called by muse, mutect2, varscan2
- TMEM184C | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 135/603 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56853724; called by muse, mutect2, varscan2
- VSIG4 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV66073835; called by muse, mutect2
- ZBTB18 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62397052; called by muse, mutect2, varscan2
- ZNF382 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV53088549, COSV53092726; called by muse, mutect2
- ZNF875 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60991515; called by muse, mutect2, varscan2
- ZUP1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 197/610 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63944401; called by muse, mutect2, varscan2
- CNST | c.1054del p.S352Rfs*2 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- COL6A3 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by muse, mutect2
- HOXA10 | c.1218_1219del p.F407* | Frame Shift Del (DEL) | VAF 48/165 reads (29%) | called by mutect2, pindel, varscan2
- MED9 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, varscan2
- NPM3 | c.240dup p.V81Cfs*10 | Frame Shift Ins (INS) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3278_3299del p.P1093Hfs*59 (on ENST00000296302 / NM_001366071.2; = p.P1068Hfs*59 on NM_018313.5) | Frame Shift Del (DEL) | VAF 116/239 reads (49%) | called by mutect2, pindel, varscan2
- SLK | c.399del p.V134* | Frame Shift Del (DEL) | VAF 97/344 reads (28%) | called by mutect2, pindel, varscan2
- SMYD4 | c.934del p.C312Afs*41 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | called by mutect2, pindel, varscan2
- VHL | c.642_*1del | Nonstop Mutation (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- WDR62 | c.3297_3301delinsTG p.S1100_S1101delinsG | In Frame Del (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2*
- ZNF564 | c.1183_1184insTT p.C395Ffs*47 | Frame Shift Ins (INS) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- C5orf22 | c.1128A>T p.I376= | Silent (SNP) | VAF 28/460 reads (6%) | catalogued as COSV57598546; called by muse, mutect2
- KDM4A | c.606T>C p.F202= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs752886841, COSV64959643; called by muse, mutect2
- NHS | c.4233C>T p.F1411= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs774186481, COSV66272605; called by muse, mutect2, varscan2
- OR56A4 | c.255C>T p.P85= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV58110349; called by muse, mutect2, varscan2
- PCDHB6 | c.2352C>A p.T784= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV50699397; called by muse, mutect2, varscan2
- PTPN21 | c.255G>A p.K85= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as COSV60848451; called by muse, mutect2, varscan2
- RFPL2 | c.813C>G p.T271= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV50711498; called by muse, mutect2
- RYR2 | c.11017C>A p.R3673= | Silent (SNP) | VAF 87/240 reads (36%) | catalogued as CM156439, COSV63687431; called by muse, mutect2, varscan2
- SLC35A2 | c.846G>A p.G282= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV54430581; called by muse, mutect2, varscan2
- SLC4A7 | c.1755G>A p.L585= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55397783; called by muse, mutect2, varscan2
- SYNE2 | c.19470C>G p.P6490= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV59952080; called by muse, mutect2
- TMEM270 | c.786T>C p.T262= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57638705; called by mutect2, varscan2
- TMEM69 | c.12C>T p.F4= | Silent (SNP) | VAF 91/290 reads (31%) | catalogued as COSV51969537; called by muse, mutect2, varscan2
- ZNF227 | c.1938T>C p.G646= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV57312491; called by muse, mutect2, varscan2
- LHCGR | c.162-1615C>T | Intron (SNP) | VAF 93/276 reads (34%) | catalogued as rs1011562166, COSV54297532; called by muse, mutect2, varscan2
